Gene-level copy-number profile of tumor specimen TCGA-AB-2866-03A from TCGA case TCGA-AB-2866, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.6 years (24,684 days).
Specimen TCGA-AB-2866-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.dada483e-9e4f-4281-959a-bdf1a1484904.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2866-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/737efb98-c15d-48b5-995b-1e8588adb08e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,381; copy number 2: 57,270; copy number 3: 167.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
